Surgical pathology report (de-identified scan), TCGA case TCGA-QK-A8ZA, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Emory University - Winship Cancer Inst., specimen TCGA-QK-A8ZA-01A (Primary Tumor).

[page 1 of 4]
Results

SURGICAL PATHOLOGY EXAM

Case Report

Case Report

Surgical Pathology Report

Case:

ICD-O-3
Carcinoma, squamous
cell NOS 8070/3
Site: Oropharynx NOS
C18.9
JW 1/17/14

Authorizing Provider:

Ordering Location:

Collected:

Pathologist:

Received:

Signed Out:

Specimen: Nasopharynx/Oropharynx

Final Diagnosis

Right oropharynx, biopsy:

- Invasive squamous cell carcinoma, moderately differentiated.
- See comment.

Comment:

A p16 immunohistochemical stain will be performed and reported in an addendum.

Clinical Information

right neck mass

Intraoperative Consultation

Patient Information

Patient Name Sex DOB SSN

[REDACTED]

[page 2 of 4]
Progress Notes signed by

Author: (none) Author Type: Physician

Filed: Note Time:

PATHOLOGY: INTRA-OPERATIVE CONSULTATION

Patient ID:

Name: Admission Date:

Sex: male

MRN: Attending Provider:

Room/Bed

Specimen/Indications: right oropharynx, mass

Report:

Right oropharynx (biopsy, FSA1, TPA1):

-Invasive moderately differentiated squamous cell carcinoma.

Electronically signed by:

Gross Description

Specimen A

Case accession number from generated container label:

Name and MRN on the initial container label, generated label, and in the electronic order are identical: YES

Specimen type and location indicated on the container label: right oropharynx

The specimen is received fresh for intraoperative consultation.

[page 3 of 4]
The specimen consists of multiple fragments of tan-pink tissue measuring 1.2 x 0.7 x 0.4 cm.

The specimen is entirely process for intraoperative consultation with frozen section and the remainder of the cryobloc is submitted in cassette labeled FSA1.

Dictated by

Addendum

Immunohistochemistry:

p16: strong diffuse positivity

Authorizing Provider Information

Name:

Phone: Pager:

PDF Results and Scans

Lab Information

Lab Lab Director

Lab Collection Information

Collection Date and Time

SURGICAL PATHOLOGY EXAM (Order

Pathology and Cytology :

[page 4 of 4]
Authorizing:

Department

Date:

Released By:

Source: NCI Genomic Data Commons file f04a7158-1a47-4bb8-be3d-e9edd5b878d4 (TCGA-QK-A8ZA.A31D16F5-71CF-49D9-A533-4D798D496153.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).